CCDI case PBCVWK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/93f00a85-7b7f-4810-b356-9e785b6a006e

Demographics
Sex at birth: male.

Biospecimens (4 samples)
- Sample 0E18HL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0E18HO, 0E27P5 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E18I4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
